Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4771, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4771-01A (Primary Tumor).

[page 1 of 2]
Ref. Source:

Clinical Diagnosis & History:

with right renal mass.

Specimens Submitted:

- 1: SP: Right kidney
- 2: SP: Retroperitoneal lymph nodes

DIAGNOSIS:

- 1) KIDNEY, RIGHT; RADICAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CLEAR CELL TYPE, WITH SARCOMATOID TRANSFORMATION, NUCLEAR GRADE IV/IV.
- THE TUMOR GREATEST DIAMETER IS 5.7 CM.
- THE TUMOR EXTENDS THROUGH THE RENAL CAPSULE BUT IS CONFINED WITHIN GEROTA'S FASCIA.
- THE TUMOR EXTENDS INTO THE RENAL SINUS FAT.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY SHOWS PATCHY CHRONIC INTERSTITIAL NEPHRITIS.
- THE ADRENAL GLAND IS NOT SUBMITTED.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF METASTATIC NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED): RENAL HILAR: 0/1.
- 2) LYMPH NODES, RETROPERITONEUM; EXCISION:
- FIVE BENIGN LYMPH NODES (0/5).

1) The specimen is received fresh, labeled, "Right kidney". It consists of a 535 grams nephrectomy specimen with attached perirenal fat, measuring 19.5 x 13.0 x 5.5 cm. The trimmed kidney weighs 290 grams and measures 11.5 x 7.0 x 5.0 cm, with a 6.0 x 0.2 x 0.2 cm segment of ureter. A firm palpable mass is identified anteriorly in the perirenal fat. The remaining external surface of the kidney is tan-brown and grossly unremarkable. The area overlying the palpable mass is inked black and the specimen is bivalved to show a 5.7 x 5.3 x 4.0 cm, well-circumscribed, tan-yellow lobulated mass with focal hemorrhage which arises in the cortex and which extends into the renal sinus. The specimen does not grossly involve the renal pelvis. The tumor abuts the overlying renal capsule, but does not grossly extend into the perirenal adipose tissue. The tumor does not grossly involve the renal vasculature. The remaining uninvolved renal parenchyma is remarkable for a 0.6 x 0.6 x 0.5 cm, cortical cyst, located in the upper pole. The remaining cortex measures 0.8 cm in greatest width and is grossly unremarkable. The adrenal gland is not identified. One possible lymph node measuring 0.4 cm in greatest dimension is identified in the renal hilar fat. Photographs are taken. Sections are taken for TPS. Representative sections are submitted.

[page 2 of 2]
Summary of Sections:

UVM – ureter and vascular margins

TUMSINUS – tumor and sinus

TUMPELV – tumor and pelvis

TUMCAPS – tumor with overlying capsule

TUMADJ – tumor with adjacent kidney

CYST -- upper pole cyst

UNKID – representative sections from uninvolved kidney

PLN -- possible lymph nodes

2) The specimen is received in formalin, labeled, "Retroperitoneal lymph nodes". It consists of multiple fragments of hemorrhagic fibroadiposa tissue measuring 4.6 x 3.5 x 1.4 cm in aggregate. Multiple lymph nodes are identified measuring from 0.3 cm to 1.4 cm in greatest dimension. All lymph nodes are submitted.

Summary of Sections:

U - undesignated

Summary of Sections:

Part 1: SP: Right kidney

Block	Sect. Site	PCs
1	cyst	1
1	pln	1
1	tumadj	1
2	tumcaps	2
1	tumpelv	1
2	tumsinus	2
2	unkid	2
1	uvm	1

Part 2: SP: Retroperitoneal lymph nodes

Block	Sect. Site	PCs
1	u	1

Source: NCI Genomic Data Commons file 9c6e645a-f222-4e60-bb54-ca5203021f5d (TCGA-BP-4771.35C69FC1-ED95-455D-B4F8-5C811F4FA791.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).